Somatic mutation profile of tumor specimen TCGA-DJ-A3UM-01A (aliquot TCGA-DJ-A3UM-01A-11D-A22D-08) from TCGA case TCGA-DJ-A3UM, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 45.4 years (16,573 days).
Specimen TCGA-DJ-A3UM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a51a5bd-2036-419e-8d67-66db35e94c19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3UM-10A (Blood Derived Normal), aliquot TCGA-DJ-A3UM-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b02f993-ed82-4bf8-bd40-6fa498d4e9c7

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ZSCAN29 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- NLRP9 | c.639C>T p.I213= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs747611549, COSV60460615; called by mutect2, varscan2
